CCDI case PBCDFM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dc7677e8-3eff-4824-8a14-2a7e8e273e59

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroepithelioma, NOS: ICD-O-3 morphology code: 9503/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,637 days).

Biospecimens (2 samples)
- Sample 0DP46Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP47P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
